Gene-level copy-number profile of tumor specimen MP2PRT-PAUKGC-TMP1-A from MP2PRT case MP2PRT-PAUKGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,185 days).
Specimen MP2PRT-PAUKGC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 259bc559-6a41-4ae9-92ad-a0ca168f3197.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUKGC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/14ac77d6-475d-4b2e-a064-fde1b618e5e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 265; copy number 1: 2,925; copy number 2: 55,543; copy number 3: 178.

Homozygous deletions (total copy number 0; autosomes only): 265 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,001,355–43,767,987, 16 genes: AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1.
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A.
- chr2:89,913,982–89,948,279, 5 genes: IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29.
- chr7:38,239,580–38,378,804, 24 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,281,105–22,552,156, 77 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,481,706, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr22:22,168,289–22,245,515, 12 genes: AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 69. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
